Surgical pathology report (de-identified scan), TCGA case TCGA-06-0208, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0208-01A (Primary Tumor).

TCGA-06-0208

PATHOLOGICAL DIAGNOSIS:

BRAIN BIOPSY: GLIOBLASTOMA MULTIFORME.

ADDENDUM REPORT: THE PROLIFERATIVE INDEX OF THIS GLIOBLASTOMA AS MEASURED BY IMMUNOSTAIN FOR MIB-1, IS ABOUT 40%.

Operation/Specimen: Brain tumor.

Clinical History and Pre-Op Dx:

GROSS PATHOLOGY:

MICROSCOPIC: Sections reveal a glioblastoma multiforme characterized by hypercellularity, marked pleomorphism, frequent mitotic figures, pronounced vasculo-endothelial hyperplasia and large areas of tumor necrosis. In less undifferentiated areas, histological pattern of oligodendroglioma is identified, suggesting that the glioblastoma evolved from an oligodendroglioma.

Source: NCI Genomic Data Commons file 8995ec3f-4fbc-451b-b159-42b4681ed0dd (TCGA-06-0208.7FD467B6-0E42-45CB-86BF-50B7C547BC9E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).